Surgical pathology report (de-identified scan), TCGA case TCGA-30-1867, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Harvard, specimen TCGA-30-1867-01A (Primary Tumor).

Accession Number: [REDACTED]

Report Status: Final

Type: Surgical Pathology

Pathology Report [REDACTED] OMENTUM BIOPSY

Accessioned On: [REDACTED]

DIAGNOSIS: [REDACTED]

TCGA-30-1867

✓ SPECIMEN LABELED "OMENTAL TUMOR" (including FSA):
METASTATIC PAPILLARY SEROUS CARCINOMA in fibroadipose tissue.

✓ SPECIMEN LABELED "RECTUS MUSCLE":

Tissue submitted to [REDACTED]

CLINICAL DATA

[REDACTED] with omental cake and mass, ascites, ?ovarian cancer.

Operation: [REDACTED]

Clinical Diagnosis: Pelvic mass

TISSUE SUBMITTED: 1. Omental tumor [REDACTED]
2. Rectus muscle

O.R. CONSULTATION:

SPECIMEN LABELED "OMENTAL TUMOR" [REDACTED]

Papillary serous carcinoma

GROSS DESCRIPTION:

The specimen is received in 2 parts, each labeled with the patient's name and unit number.

Part 1, "omental tumor", consists of a 4 x 2.5 x 1.5 cm fragment of yellow/white soft tissue which is firm and largely replaced by tumor. A representative section is frozen and submitted as "FSA" and representative sections are submitted to [REDACTED] lab.

Micro 1 - FSA remnant, 1 frag, [REDACTED]

Micro 2-4 - omental tumor, 7 fra [REDACTED]

Part 2, "rectus muscle", consists of a piece of red muscle (1.5 x 0.7 x 0.5 cm) which is entirely submitted to [REDACTED]

Reports to: [REDACTED]

SPECIMEN TYPE: OMENTUM BIOPSY

ADDITIONAL SPECIMEN TYPE: TISSUE FOR SPECIAL STUDIES ONLY

Source: NCI Genomic Data Commons file c23a07a5-f8d9-4806-a9bb-2fd894f46aba (TCGA-30-1867.420A6B8C-33B8-4B1E-8BBA-E299C20611C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).